Somatic mutation profile of tumor specimen TCGA-06-6391-01A (aliquot TCGA-06-6391-01A-11D-1696-08) from TCGA case TCGA-06-6391, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 44.4 years (16,206 days).
Specimen TCGA-06-6391-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a29198ce-53af-40cd-ae47-3033c8786c5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-6391-10A (Blood Derived Normal), aliquot TCGA-06-6391-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf84ce29-6631-43bc-979b-426350d89d95

The open-access MAF lists 71 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Nonsense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 143/284 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.10654G>C p.G3552R | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51959016; called by muse, mutect2, varscan2
- APOB | c.2726C>T p.S909L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs776209966, COSV51931224; called by muse, mutect2, varscan2
- BEST2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as rs368197840; called by muse, mutect2, varscan2
- C12orf40 | c.1684A>G p.N562D | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1372583033, COSV61138544; called by muse, mutect2, varscan2
- C12orf40 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767767359; called by muse, varscan2
- CCDC158 | c.1857G>T p.K619N | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs756860152, COSV101187127, COSV66356856; called by muse, mutect2, varscan2
- CCR5 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 49/287 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as rs746300015; called by muse, mutect2, varscan2
- CD163 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs747400028, COSV63136046, COSV99051821; called by muse, mutect2, varscan2
- DNAH5 | c.3613G>A p.A1205T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs767655417, COSV54226869; called by muse, mutect2, varscan2
- EAF2 | c.333A>T p.K111N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56545488; called by muse, mutect2, varscan2
- HEATR5A | c.4298G>A p.R1433K | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs1260918391, COSV101119964; called by muse, mutect2, varscan2
- IL12RB2 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs141507006; called by muse, mutect2, varscan2
- MTF1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs774690246; called by muse, mutect2, varscan2
- MYH11 | c.4972C>G p.Q1658E | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.405); catalogued as rs766356741; called by muse, mutect2, varscan2
- PRAMEF20 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs779646091, COSV57080721; called by muse, mutect2, varscan2
- PRKCB | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1205851470; called by muse, mutect2, varscan2
- SCN10A | c.4594C>T p.Q1532* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV71862487; called by muse, mutect2, varscan2
- SERPINB4 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs781536461, COSV61986289; called by muse, mutect2, varscan2
- SLC2A13 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.549); catalogued as rs1407291378; called by muse, mutect2, varscan2
- SORBS1 | c.3034G>C p.E1012Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99528884; called by muse, mutect2, varscan2
- STEAP4 | c.866G>T p.C289F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs79363691; called by muse, mutect2, varscan2
- VPS50 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV52496855; called by muse, mutect2, varscan2
- ALX1 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ATRX | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 66/317 reads (21%) | called by muse, mutect2, varscan2
- C12orf40 | c.1889A>C p.N630T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, varscan2
- CDKL5 | c.1132C>G p.P378A | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP47 | c.560T>A p.I187N | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CYP2B6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- EPM2A | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HAL | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- HTR1D | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- IARS1 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KL | c.1486T>C p.F496L | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MAOB | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MBNL1 | c.575A>T p.N192I | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- NTRK1 | c.797G>A p.W266* | Nonsense Mutation (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
- OR10Q1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- OR3A2 | c.528C>G p.N176K | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHA3 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PDGFD | c.826A>G p.N276D | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPRR | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 50/274 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.265); called by muse, varscan2
- R3HDM2 | c.1094G>C p.S365T | Missense Mutation (SNP) | VAF 42/657 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- RERGL | c.208C>A p.L70I | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RPL36A | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SIPA1L2 | c.3962C>T p.S1321F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SLC26A8 | c.2189T>A p.M730K | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SPINT1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SRP54 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SUGCT | c.1189G>C p.E397Q (on ENST00000335693 / NM_001193313.2; = p.E423Q on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.131); called by muse, varscan2
- TPSAB1 | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAM1 | c.117G>T p.M39I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- TRAV9-1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF142 | c.2447G>A p.G816E (on ENST00000411696 / NM_001379660.1; = p.G616E on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.87); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ASB18 | c.1260C>T p.T420= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100430858; called by muse, mutect2
- DCAF8L1 | c.1005C>G p.V335= | Silent (SNP) | VAF 18/123 reads (15%) | catalogued as rs774251829, COSV71595240; called by muse, mutect2, varscan2
- DNAH3 | c.2010C>T p.A670= | Silent (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- DNM1 | c.75G>A p.Q25= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- EZH2 | c.2106T>A p.V702= (on ENST00000460911 / NM_001203247.2; = p.V707= on NM_004456.5) | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- GUCY2C | c.237C>T p.N79= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs765471670, COSV99663665; called by muse, mutect2, varscan2
- LRRC8D | c.1677C>G p.L559= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- MROH2B | c.1278A>G p.E426= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, mutect2, varscan2
- MYO16 | c.5576G>A p.*1859= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- NEB | c.10092C>T p.P3364= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as rs375814899; called by muse, mutect2
- OR5AU1 | c.813C>T p.D271= | Silent (SNP) | VAF 14/112 reads (13%) | called by muse, mutect2, varscan2
- SEMA3G | c.2112G>A p.K704= | Silent (SNP) | VAF 43/190 reads (23%) | catalogued as rs1350658238; called by muse, mutect2, varscan2
- SLC35E1 | c.1131C>T p.H377= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as rs139815009; called by muse, mutect2, varscan2
- TBC1D4 | c.63C>T p.G21= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- TXK | c.490T>C p.L164= | Silent (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7392G>A p.S2464= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs761611371, COSV50650716, COSV50683357; called by muse, mutect2, varscan2
- MYB | c.1203+1049C>A | Intron (SNP) | VAF 9/178 reads (5%) | called by muse, mutect2
